Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A0ZQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A0ZQ-01A (Primary Tumor).

[page 1 of 2]
Adenocarcinoma, endometrioid, NOS
8380/3

Site Code: Endometrium C54.1 1/17/11 lw

DIAGNOSIS:

A. Uterus, right and left ovaries and fallopian tubes, hysterectomy, and bilateral salpingo-oophorectomies:

Residual FIGO

grade 2 (of 3) endometrial adenocarcinoma, endometrioid type with

mucinous differentiation, is identified forming a mass (2.7 x 2.6 x

0.7 cm) located in the left cornu and posterior aspect of uterine

fundus. No residual papillary serous component is identified. The

tumor invades 1.2 cm into the myometrium (total wall thickness, 2.0

cm). The tumor does not involve the endocervix.

Lymphovascular

space invasion is not identified. The margins are negative for

tumor. The right ovary shows a peritoneal inclusion cyst.

The left

ovary shows a serous cystadenoma. Both fallopian tubes are unremarkable. [AJCCpT1cNxMx].

p53 shows weak and spotty immunoreactivity, supporting the above

diagnosis.

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Uterus, right and left ovaries and fallopian tubes, hysterectomy, and bilateral salpingo-oophorectomies:

Invasive

endometrial adenocarcinoma. Hold for tumor typing.

GROSS DESCRIPTION:

Received fresh labeled "uterus, bilateral tubes and ovaries" is a

95.0 gram uterus with attached bilateral tubes and ovaries and an

unremarkable cervix. The uterine serosa is smooth. There is a 2.7 x

2.6 x 0.7 cm mass in the left cornu and posterior fundus with 1.2 cm

[page 2 of 2]
myometrial invasion (total myometrial thickness 2.0 cm).
There are

5 uterine intramural and subserosal leiomyomas ranging
from 0.4 cm

to 1.5 cm in greatest dimension. There is a 4.6 x 3.1 x
2.8 cm right

ovary with a ragged outer surface and a cystic (2.2 cm)
cut surface

with an 8.9 x 0.5 cm right fallopian tube. There is a
3.2 x 2.0 x

1.6 cm left ovary with a ragged outer surface and a solid
and cystic

cut surface with a 7.2 x 0.5 cm left fallopian tube.

Representative

sections submitted.

BLOCK SUMMARY:

Part A: Uterus, tubes, ovaries

- 1 Endometrial tumor 1
- 2 Endometrial tumor 2
- 3 Endometrial tumor 3
- 4 Cervix 6:00
- 5 Lower uterine segment
- 6 Right fallopian tube
- 7 Right ovary
- 8 Left tube
- 9 Left ovary
- 10 Myometrium
- 11 Left ovary #2
- 12 Myometrium #2

Source: NCI Genomic Data Commons file bb0b403e-9a23-42db-82ca-11eff055230c (TCGA-D1-A0ZQ.BAC6E925-0499-41AD-9F58-2CB8E3EE058E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).